Somatic mutation profile of tumor specimen TARGET-40-PASFCV-01A (aliquot TARGET-40-PASFCV-01A-01D) from TARGET case TARGET-40-PASFCV, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 10.5 years (3,849 days).
Specimen TARGET-40-PASFCV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d203eb35-17c8-460e-87d0-75223504c21c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PASFCV-10A (Blood Derived Normal), aliquot TARGET-40-PASFCV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2650638b-43db-458a-afde-fe17e3eb254d

The open-access MAF lists 26 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, RNA 3, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANGPTL7 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 24/241 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776556084, COSV100815875; called by muse, mutect2, varscan2
- CCDC144A | c.4012C>A p.L1338I | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs1455131584; called by muse, mutect2
- FERMT3 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745962281; called by muse, mutect2, varscan2
- OSBPL10 | c.1972G>C p.E658Q | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV67338727; called by muse, mutect2, varscan2
- RYR2 | c.3151C>T p.R1051C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.905); catalogued as rs533330664, COSV63683432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF15 | c.774C>G p.H258Q | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2
- ATP8B2 | c.2911A>G p.K971E (on ENST00000672630; = p.K938E on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/195 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- BCORL1 | c.1955C>G p.T652S | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC33 | c.870G>C p.E290D | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CSPG4 | c.5363A>C p.H1788P | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT2 | c.2624T>C p.L875P | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- MRM1 | c.46G>C p.V16L | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM5 | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- SOX2 | c.478T>C p.Y160H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- TSPAN12 | c.11A>G p.E4G | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF224 | c.1488T>G p.N496K | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ANO5 | c.1146A>T p.S382= | Silent (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- CTDNEP1 | c.159G>A p.R53= | Silent (SNP) | VAF 66/131 reads (50%) | catalogued as rs943757823; called by muse, mutect2, varscan2
- MRPL13 | c.39T>C p.T13= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- NRXN1 | c.2949C>T p.L983= | Silent (SNP) | VAF 27/253 reads (11%) | catalogued as rs1558830631; called by muse, mutect2, varscan2
- PLXNA3 | c.2013C>T p.S671= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- ZNF185 | c.879A>G p.G293= | Silent (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- AC025884.1 | n.22C>T | RNA (SNP) | VAF 28/500 reads (6%) | catalogued as rs764452267; called by muse, mutect2
- FAM27E5 | n.385G>T | RNA (SNP) | VAF 24/199 reads (12%) | catalogued as rs369352933; called by muse, mutect2, varscan2
- RPS26P15 | n.163G>T | RNA (SNP) | VAF 55/232 reads (24%) | called by muse, mutect2, varscan2
- TRIM28 | c.1982+24C>G | Intron (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
